MMRF case MMRF_2232 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/bf14ca10-5310-44a6-964c-99b13f0b2e11

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 56 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 56.1 years (20,478 days); ISS stage: I; Days to last known disease status: 800 days (2.2 years); Days to last follow up: 800 days (2.2 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 50 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 53 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 57 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 80 days; Days to treatment end: 80 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 99 days; Days to treatment end: 99 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 100 days; Days to treatment end: 100 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 176 days; Days to treatment end: 207 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 227 days; Days to treatment end: 310 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 311 days; Days to treatment end: 380 days (1.0 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 381 days (1.0 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -18 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 357 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.07 mg/dL; Immunoglobulin G 9.1 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 2.5 µg/mL; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 236 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.58 mmol/L; Albumin 42 g/L; Total Protein 7.4 g/dL; Glucose 4.35 mmol/L; C-Reactive Protein 1.41 mg/dL.
- Day 79 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 19.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.23 mg/dL; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 377 ×10⁹/L; Creatinine 44.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 7.1 g/dL; Glucose 5.45 mmol/L.
- Day 169 (ECOG 1): M Protein 0.39 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.65 mg/dL; Immunoglobulin G 12.6 g/L; Immunoglobulin A 1.63 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 4.3 µg/mL; Lactate Dehydrogenase 3.62 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 281 ×10⁹/L; Creatinine 44.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 7.5 g/dL; Glucose 4.07 mmol/L.
- Day 255 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.22 mg/dL; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 259 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 4.07 mmol/L.
- Day 339 (ECOG 1): M Protein 0.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.42 mg/dL; Lactate Dehydrogenase 2.25 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 230 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 7.2 g/dL; Glucose 4.24 mmol/L.
- Day 437 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.92 mg/dL; Lactate Dehydrogenase 2.2 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 7.3 g/dL; Glucose 3.58 mmol/L.
- Day 521 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.55 mg/dL; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 275 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 7.7 g/dL; Glucose 4.18 mmol/L.
- Day 605 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.33 mg/dL; Lactate Dehydrogenase 1.97 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.13 mmol/L; Albumin 35 g/L; Total Protein 6.6 g/dL; Glucose 5.45 mmol/L.
- Day 688 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.58 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 3.91 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 246 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 6.7 g/dL; Glucose 4.84 mmol/L.
- Day 800 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.09 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 3.88 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 1.92 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 245 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 6.9 g/dL; Glucose 3.3 mmol/L.

Other clinical attributes
- Day -18: Weight: 84 kg; Height: 175 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2232_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -18 days.
- Sample MMRF_2232_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -18 days.
